Gene-level copy-number profile of tumor specimen ALCH-B2U2-TTP1-A from ALCHEMIST case ALCH-B2U2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.8 years (19,287 days).
Specimen ALCH-B2U2-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b6da5b1c-046a-46de-bb5b-dc77e58d43e6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2U2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/22f9213c-1bb7-4102-9c3d-059408fcbca3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 157; copy number 1: 12,298; copy number 2: 42,421; copy number 3: 2,103; copy number 4: 763; copy number 5: 131; copy number 6: 153; copy number 7: 19; copy number 8: 95; copy number 9: 23; copy number 10: 9; copy number 11: 34; copy number 12: 23; copy number 14: 65; copy number 15: 4; copy number 16: 54; copy number 18: 2; copy number 25: 36.

Homozygous deletions (total copy number 0; autosomes only): 157 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,252,820–52,551,574, 3 genes: AC097522.2, AC097522.1, RNU6-1252P.
- chr9:5,231,419–5,235,304, 1 gene: INSL4.
- chr9:15,553,043–18,910,950, 22 genes: CCDC171, HMGN2P16, RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1, SH3GL2, PABPC1P11, ADAMTSL1, AL442638.1, MIR3152, RN7SKP258, RAP1BP1.
- chr9:20,331,446–26,644,595, 87 genes (broad region; genes not listed).
- chr9:27,325,209–27,844,481, 8 genes (within-gene range 0–8): MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1.
- chr9:61,190,003–61,582,675, 8 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr15:25,159,221–25,209,999, 24 genes (within-gene range 0–1): SNORD115, DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22.
- chr15:90,839,641–90,853,608, 1 gene: AC124248.1.
- chr16:33,802,764–33,803,217, 1 gene: IGHV3OR16-12.
- chr16:33,976,039–33,991,551, 2 genes (within-gene range 0–1): AC133561.1, BCAP31P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 648 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,674,857–91,685,884, 2 genes, copy number 5: RNA5SP100, DRD5P1.
- chr7:63,011,463–63,263,456, 12 genes, copy number 5: RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7.
- chr7:64,566,814–73,207,283, 163 genes, copy number 6–14 (broad region; genes not listed).
- chr7:73,440,406–73,736,158, 13 genes, copy number 5 (within-gene range 2–5): BAZ1B, RNU6-1198P, BCL7B, TBL2, MLXIPL, AC005089.1, VPS37D, DNAJC30, BUD23, STX1A, MIR4284, RN7SL265P, ABHD11-AS1.
- chr7:74,231,499–75,031,528, 16 genes, copy number 5 (within-gene range 2–5): RFC2, CLIP2, GTF2IRD1, RNA5SP233, AC211433.2, AC211433.3, GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2, STAG3L2, PMS2P5, Y_RNA, SPDYE12P, CASTOR2.
- chr7:77,122,434–77,462,139, 6 genes, copy number 10 (within-gene range 2–10): CCDC146, FGL2, AC098851.1, GSAP, AC004921.1, GCNT1P5.
- chr7:99,027,440–99,144,108, 2 genes, copy number 6: SMURF1, AC004893.1.
- chr7:99,546,300–99,632,408, 5 genes, copy number 10–12: FAM200A, ZNF655, AC005020.2, TMEM225B, ZSCAN25.
- chr9:1,977,784–4,348,392, 24 genes, copy number 6–9 (within-gene range 1–9): AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1, GLIS3, AL137071.1, GLIS3-AS1, AL359095.1.
- chr9:26,746,953–27,297,150, 16 genes, copy number 8: AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN.
- chr9:27,937,617–30,690,272, 15 genes, copy number 6: AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2.
- chr9:136,754,386–136,800,595, 5 genes, copy number 5 (within-gene range 4–5): LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3.
- chr12:59,523,278–75,984,015, 280 genes, copy number 5–25 (broad region; genes not listed).
- chr12:125,808,668–125,901,483, 4 genes, copy number 15: AC005252.2, AC005252.4, AC005252.3, AC005252.1.
- chr12:127,344,258–127,372,669, 2 genes, copy number 6: AC073913.2, AC048347.1.
- chr14:18,333,726–18,341,859, 1 gene, copy number 9: CR383658.1.
- chr16:51,553,436–52,099,120, 8 genes, copy number 6: HNRNPA1P48, RN7SKP142, LINC01571, C16orf97, AC009039.1, AC009039.2, LINC00919, LINC02180.
- chr16:54,239,693–55,833,337, 31 genes, copy number 8: AC007907.1, LINC02169, IRX3, AC018553.2, AC018553.1, LINC02140, AC018553.3, CRNDE, AC106742.1, IRX5, AC106738.1, AC106738.2, MTND5P34, AC109462.1, RN7SL841P, AC109462.3, IRX6, AC109462.2, RPL31P56, MMP2, AC007336.2, MMP2-AS1, AC007336.3, LPCAT2, AC007336.1, CAPNS2, SLC6A2, AC136621.1, CES1P2, CES1P1, CES1.
- chr16:56,191,390–56,983,845, 43 genes, copy number 8: GNAO1, DKFZP434H168, MIR3935, AC009102.4, AC009102.1, AC009102.3, AC009102.2, AMFR, AC092140.1, NUDT21, OGFOD1, AC092140.2, BBS2, MT4, MT3, MT2A, AC026461.3, MT1L, MT1E, MT1M, MT1JP, MT1A, MT1DP, MT1CP, AC026461.2, MT1B, MT1F, MT1G, MT1H, MT1IP, MT1X, AC026461.1, DPPA2P4, AC106779.1, NUP93, MIR138-2, SLC12A3, MIR6863, RPS24P17, HERPUD1, AC012181.2, AC012181.1, CETP.

Autosomal genes at a single copy (total copy number 1): 11,770. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
